Gene-level copy-number profile of tumor specimen C3N-02033-03 from CPTAC case C3N-02033, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.8 years (28,057 days).
Specimen C3N-02033-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e80b5172-949e-42e5-a6f2-0d7a22f23658.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02033-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/54892281-ebce-482a-8471-a7649c233dc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 3,881; copy number 2: 41,100; copy number 3: 8,418; copy number 4: 4,874; copy number 6: 1; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–27,844,481, 110 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr10:87,751,512–87,994,695, 8 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,474,745–166,580,705, 3 genes, copy number 7: FMO7P, LINC01675, FMO8P.
- chr8:39,451,045–39,522,852, 1 gene, copy number 6: ADAM3A.

Autosomal genes at a single copy (total copy number 1): 2,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
